Somatic mutation profile of tumor specimen 0DK5HJ from CCDI case PBBXTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 15.1 years (5,524 days).
Specimen 0DK5HJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8e896d1-c21d-452d-9bd6-b0769ea84ac1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK5HP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae3a07fe-de95-4f1e-8298-9a750f3e8b5e

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9L | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 101/424 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs372773894; called by muse, mutect2, varscan2
- CFAP47 | c.5141C>T p.S1714F | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV57976674; called by muse, mutect2
- POLD2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1418978488; called by muse, mutect2, varscan2
- RANBP1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 25/581 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- RFTN2 | c.680dup p.N227Kfs*8 | Frame Shift Ins (INS) | VAF 87/486 reads (18%) | called by mutect2, pindel, varscan2
